Surgical pathology report (de-identified scan), TCGA case TCGA-P4-AAVL, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site  MD Anderson Cancer Center, specimen TCGA-P4-AAVL-01A (Primary Tumor).

Department of PathologyUUID: 2EC576D3-78D2-475A-9F83-92F712A60EFB

Tissue Source Site (TSS) #:

Pathology Accession No:

Patient ID:

Normal Sample ID:

**Pathology Report****DIAGNOSIS****(A) IVC TUMOR THROMBUS:**

RENAL CELL CARCINOMA ADMIXED WITH FIBRIN, RED BLOOD CELLS AND BLOOD VESSELS CONSISTENT WITH A TUMOR THROMBUS.

(B) LEFT KIDNEY, RENAL VEIN THROMBUS, ADRENAL:

RENAL CELL CARCINOMA, PAPILLARY TYPE 2, FUHRMAN NUCLEAR GRADE 4 WITH FOCAL SARCOMATOID DEDIFFERENTIATION (APPROXIMATELY 10%).

TUMOR MEASURES 4.8 X 4.5 X 4.0 CM.

TUMOR INFILTRATES RENAL SINUS ADIPOSE TISSUE AND PERINEPHRIC ADIPOSE TISSUE.

TUMOR FORMS A RENAL VEIN THROMBUS AND FOCALLY INVADES THE VESSEL WALL AT THE RENAL VEIN RESECTION MARGIN.

Renal artery, ureteral and peripheral soft tissue resection margins, free of tumor.

Simple renal cysts.

Adrenal gland, no tumor present.

(C) PARAAORTIC LYMPH NODES:

METASTATIC RENAL CELL CARCINOMA PRESENT IN ONE OF TWENTY-ONE LYMPH NODES, (1/21).

METASTATIC FOCUS MEASURES 1.0 MM IN MAXIMUM DIMENSION.

No extranodal extension is present.

GROSS DESCRIPTION**(A) IVC TUMOR THROMBUS** - An unoriented friable 1.5 x 1.2 x 0.7 cm portion of soft tissue, entirely submitted in A.**(B) LEFT KIDNEY, RENAL VEIN THROMBUS, ADRENAL** - A radical nephrectomy specimen (19.5 x 12.0 x 5.0 cm) including the kidney (11.0 x 6.0 x 8.5 cm), a segment of renal artery, renal vein containing thrombus and ureter (10.0 cm length x 0.5 cm average diameter and adrenal gland (3.1 x 2.0 x 0.7 cm).

There is a 4.8 x 4.5 x 4.0 cm well circumscribed variegated tumor in the midportion of the kidney that is yellow-tan to white-tan with extensive areas of hemorrhage and necrosis present predominantly at the periphery of the tumor. The tumor is confined to the kidney but appears to distend the renal capsule as well as Gerota's fascia (black). The tumor does not appear to invade into perinephric adipose tissue. The tumor abuts the renal sinus and appears to extend into the renal vein.

The adjacent kidney parenchyma is unremarkable apart from simple renal cortical cyst ranging in size from 0.5 to 3.0 cm in greatest dimensions.

The pelvicalyceal system is smooth and devoid of any lesions. No lymph nodes are identified in the hilum of the kidney.

Serial cross sections of the left adrenal gland show unremarkable cortex and medulla.

INK CODE: Black - Gerota's fascia closest to tumor.

SECTION CODE: B1, ureter, renal artery and renal vein margin, en face; B2, B3, renal sinus and tumor; B4-B5, tumor in relationship to Gerota's fascia and perinephric fat; B6, tumor in relationship to kidney; B7, tumor in relationship to perinephric fat; B8, B9, unremarkable kidney with renal cysts; B10, adrenal gland.

(C) PARA-AORTIC LYMPH NODES - A 5.0 x 3.0 x 1.5 cm portion of fibroadipose tissue. The specimen is dissected to reveal twenty possible lymph nodes ranging from 0.2 up to 2.0 cm in greatest dimension. The specimen is submitted entirely.

SECTION CODE: C1, five possible lymph nodes; C2, five possible lymph nodes; C3, four possible lymph nodes; C4, three possible lymph nodes; C5, two possible lymph nodes; C6, one possible lymph node bisected.

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, T-C4400, M-Y7343, M-Y5493, M-Y7346

ICD-O-3

Carcinoma, papillary renal cell 8260/3
Site (C) Kidney NOS C64.9
JW 5/19/14

Source: NCI Genomic Data Commons file e84724cd-08cc-4747-b39a-d65d4adf0180 (TCGA-P4-AAVL.2EC576D3-78D2-475A-9F83-92F712A60EFB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).